Surgical pathology report (de-identified scan), TCGA case TCGA-ET-A3BW, project TCGA-THCA (Thyroid Carcinoma), tissue source site Johns Hopkins, specimen TCGA-ET-A3BW-01A (Primary Tumor).

Local/Sym-chronous Primary Noted		☒
	hw	10/15/11

SPECIMEN TAKEN:

FINAL DIAGNOSIS -----

THYROID, LEFT LOBE AND ISTHMUS (HEMITHYROIDECTOMY):

TUMOR SITE:

Left lobe.

1CD-0-3

Carcinoma, papillary, thyroid

HISTOLOGIC TYPE:

Papillary carcinoma, conventional type.

8260/3

Site: Thyroid, Nos C73.9

TUMOR SIZE:

Greatest dimension: 3.2 cm.

hw
10/15/11

FOCALITY:

Multifocal: there is a second 0.4 cm papillary microcarcinoma.

LYMPH NODES:

None submitted.

EXTENT OF INVASION (7th Edition AJCC):

PRIMARY TUMOR:

pT2: Tumor >2cm but <4cm, limited to thyroid.

REGIONAL LYMPH NODES:

pNx: Cannot be assessed.

DISTANT METASTASIS:

pMx: Cannot be assessed.

MARGINS:

Margins are uninvolved.

VENOUS/LYMPHATIC INVASION:

Absent.

ADDITIONAL PATHOLOGIC FINDINGS:

Follicular adenoma (1.2 cm).

Source: NCI Genomic Data Commons file 53117db7-5783-4ca0-9308-ceaa9e63b456 (TCGA-ET-A3BW.3F6367E6-F1F2-4019-A95B-EF5D78054A2B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).